Gene-level copy-number profile of tumor specimen REBC-ADK0-TTP1-A from REBC case REBC-ADK0, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADK0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2c4e9d50-234b-4eb2-afd6-2ce75ff6f698.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADK0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/199f8c9a-6a65-42a1-9e0f-3b0c772ba13d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 68; copy number 2: 58,143; copy number 3: 93; copy number 4: 1; copy number 5: 96.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:113,667,219–113,751,089, 2 genes: GRK1, LINC00552.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 96 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,739,857–196,832,647, 1 gene, copy number 5 (within-gene range 2–5): PAK2.
- chr3:196,784,980–196,785,086, 1 gene, copy number 5: RNU6-42P.
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,257,879–38,378,804, 21 genes, copy number 5 (within-gene range 2–5): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr14:21,950,406–22,499,749, 71 genes, copy number 5 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
